Somatic mutation profile of tumor specimen TCGA-12-1602-01A (aliquot TCGA-12-1602-01A-01W-0643-08) from TCGA case TCGA-12-1602, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.8 years (21,492 days).
Specimen TCGA-12-1602-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9af5ea6a-68c6-4b2e-873c-47f94d9cd90d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-1602-10A (Blood Derived Normal), aliquot TCGA-12-1602-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f79f3ad9-df99-4a9f-b928-6e0243c9b8b9

The open-access MAF lists 46 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, RNA 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGMO | c.356C>A p.S119* | Nonsense Mutation (SNP) | VAF 42/117 reads (36%) | catalogued as COSV100694640, COSV61106296; called by muse, mutect2, varscan2
- AMHR2 | c.1663G>A p.V555I | Missense Mutation (SNP) | VAF 84/108 reads (78%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs755889478, COSV57685901; called by muse, mutect2, varscan2
- CALN1 | c.136C>T p.R46W (on ENST00000329008 / NM_001017440.3; = p.R88W on NM_031468.4) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV61119319; called by muse, mutect2, varscan2
- CCN4 | c.328T>A p.Y110N | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99137347; called by muse, mutect2
- CDH19 | c.1462A>C p.I488L | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV100052113; called by muse, mutect2, varscan2
- CHD2 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100560856; called by muse, mutect2, varscan2
- CLDN8 | c.529G>T p.V177F | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99729979; called by muse, mutect2, varscan2
- CYP4F2 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 138/362 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751427624, COSV99686261; called by muse, mutect2, varscan2
- DYNC1I1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs780509560, COSV61456615; called by muse, mutect2, varscan2
- GALNT17 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1380419401, COSV61176649, COSV61194625; called by muse, mutect2, varscan2
- GK2 | c.418A>G p.K140E | Missense Mutation (SNP) | VAF 193/360 reads (54%) | SIFT tolerated (0.85); PolyPhen benign (0.033); catalogued as COSV100726028, COSV62626329; called by muse, mutect2, varscan2
- HSD11B1 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373816985, COSV99808336; called by muse, mutect2, varscan2
- IRS1 | c.2377A>G p.T793A | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100524871, COSV59334469; called by muse, mutect2, varscan2
- KDR | c.2884C>T p.R962C | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1312670638, COSV55758234; called by muse, mutect2, varscan2
- LEPR | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 154/292 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138922570; called by muse, mutect2, varscan2
- MKRN2 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs1379680230, COSV50104174; called by muse, mutect2, varscan2
- OR1F1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 99/182 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV100484494; called by muse, mutect2, varscan2
- OR4K13 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 61/72 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs773192410, COSV100237863; called by muse, mutect2, varscan2
- OR5R1 | c.26T>A p.V9D | Missense Mutation (SNP) | VAF 55/77 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100393557; called by muse, mutect2, varscan2
- OR7C1 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 112/297 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1384199647, COSV50182932; called by muse, mutect2, varscan2
- POP1 | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 313/778 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs142902409; called by muse, mutect2, varscan2
- PTPRH | c.3251C>T p.A1084V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV99671388; called by muse, varscan2
- RIT2 | c.502T>A p.F168I | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (1); PolyPhen possibly damaging (0.63); catalogued as COSV100451689; called by muse, mutect2, varscan2
- SIM1 | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs149142065; called by muse, mutect2, varscan2
- SLC13A3 | c.396G>A p.M132I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99287172; called by muse, mutect2, varscan2
- SLCO1B1 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 162/276 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763991908, COSV57012971; called by muse, mutect2, varscan2
- SP1 | c.1269G>C p.Q423H (on ENST00000327443 / NM_138473.3; = p.Q416H on NM_003109.1) | Missense Mutation (SNP) | VAF 22/551 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100540822; called by muse, mutect2
- SYMPK | c.730G>C p.V244L | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV55609691, COSV99842011, COSV99842029; called by muse, mutect2, varscan2
- TTC30A | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 105/414 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100826226; called by muse, mutect2, varscan2
- ZNF317 | c.44C>A p.S15Y | Missense Mutation (SNP) | VAF 128/309 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV99927329; called by muse, mutect2, varscan2
- ZNF572 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.471); catalogued as rs201968418, COSV60002199; called by muse, mutect2, varscan2
- FZD4 | c.175A>G p.N59D | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CCL4 | c.255C>T p.Y85= | Silent (SNP) | VAF 58/159 reads (36%) | catalogued as rs371375580; called by muse, mutect2
- ENTPD6 | c.693C>T p.T231= | Silent (SNP) | VAF 28/227 reads (12%) | catalogued as rs780503838, COSV100737166; called by muse, mutect2, varscan2
- OR5H14 | c.651T>A p.S217= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV101454261; called by muse, varscan2
- PCDHA9 | c.1575C>T p.H525= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100970012; called by muse, varscan2
- RNF216 | c.2091C>T p.A697= (on ENST00000425013 / NM_207116.3; = p.A754= on NM_207111.4) | Silent (SNP) | VAF 5/104 reads (5%) | catalogued as COSV101111374; called by muse, mutect2
- SMU1 | c.1146A>G p.E382= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV101238580; called by muse, mutect2
- SPAG17 | c.3138T>A p.I1046= | Silent (SNP) | VAF 62/269 reads (23%) | catalogued as COSV100310260; called by muse, mutect2
- TCHH | c.5802C>T p.I1934= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs561308210, COSV100915375; called by muse, mutect2, varscan2
- TMEM132D | c.1956T>C p.A652= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV101243046; called by muse, mutect2
- TMEM132D | c.780C>T p.S260= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs1210064135, COSV70604469, COSV70608955; called by muse, mutect2, varscan2
- UTY | c.2946C>T p.Y982= | Silent (SNP) | VAF 67/73 reads (92%) | catalogued as COSV100229819; called by muse, mutect2, varscan2
- DCHS2 | n.6110C>T | RNA (SNP) | VAF 27/109 reads (25%) | catalogued as COSV100602477; called by muse, mutect2, varscan2
- MIR302F | n.18A>G | RNA (SNP) | VAF 116/310 reads (37%) | called by muse, mutect2, varscan2
- SNAP25 | c.164-262G>A | Intron (SNP) | VAF 119/276 reads (43%) | catalogued as rs1431916684, COSV54770791; called by muse, mutect2, varscan2
